Gene-level copy-number profile of tumor specimen TCGA-FD-A3B7-01A from TCGA case TCGA-FD-A3B7, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Lateral wall of bladder; AJCC pathologic stage: Stage III; Tumor grade: High Grade; Age at diagnosis: 66.4 years (24,245 days).
Specimen TCGA-FD-A3B7-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-BLCA.c9144301-5067-4527-a057-7ca5a43a8637.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-FD-A3B7-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 804 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/c1871477-cd5f-4e7d-80a5-c6041f5a35e2

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 153; copy number 1: 21,757; copy number 2: 29,875; copy number 3: 5,480; copy number 4: 1,986; copy number 5: 221; copy number 6: 19; copy number 7: 42; copy number 8: 30; copy number 9: 127; copy number 10: 22; copy number 11: 2; copy number 12: 53; copy number 16: 52.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-FD-A3B7-01A-31D-A20B-01): tumor purity 0.28, ploidy 2.17, whole-genome doublings 0.

Homozygous deletions (total copy number 0; autosomes only): 153 genes in 2 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:151,670,504–151,761,007, 1 gene (within-gene range 0–5): GATB.
- chr4:151,798,917–159,777,828, 152 genes (broad region; genes not listed).

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 568 genes in 10 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:117,834,145–121,118,734, 51 genes, copy number 7–9: LINC02264, NDST3, FKBP4P1, SNHG8, SNORA24, PRSS12, NDUFS5P5, AC092670.1, CEP170P1, AC110079.1, RNU6-1054P, CICP16, SEPTIN14P4, METTL14-DT, METTL14, SEC24D, SYNPO2, AC096745.1, MYOZ2, AC092656.1, USP53, C4orf3, FABP2, KLHL2P1, RNU4-33P, AC110373.1, GTF2IP12, AC093752.3, RNU6-1217P, AC093752.1, AC093752.2, PDE5A, AC080089.1, AC080089.2, LINC01365, AC097173.1, LINC02502, Y_RNA, AC097173.2, MAD2L1, AC073475.1, LTV1P1, SAR1AP3, AC025741.1, PRDM5, RNU6-550P, SETP12, NDNF, RN7SKP137, AC105254.1, AC105254.2.
- chr4:121,667,946–122,922,968, 23 genes, copy number 8: ANXA5, TMEM155, PP12613, EXOSC9, CCNA2, BBS7, AC079341.1, TRPC3, AC097533.1, RN7SL335P, KIAA1109, ADAD1, IL2, IL21, IL21-AS1, AC053545.1, CETN4P, BBS12, AC021205.2, FGF2, AC021205.1, AC021205.3, NUDT6.
- chr4:137,518,918–151,670,503, 212 genes, copy number 5–16 (broad region; genes not listed).
- chr4:151,674,483–151,677,893, 1 gene, copy number 5: AC092611.1.
- chr6:5,664,985–8,760,447, 56 genes, copy number 5: AL022097.1, AL136968.2, AL136968.1, AL136307.1, RN7SL221P, PKMP5, NRN1, F13A1, MIR7853, MIR5683, LY86-AS1, SNAPC5P1, AL162719.1, CNN3P1, LY86, AL031123.2, AL031123.3, AL031123.1, AL031123.4, AL031123.5, AL136361.1, BTF3P7, AL158817.1, RN7SL554P, AL139390.1, RREB1, AL355336.1, Y_RNA, AL589644.1, AL139095.5, SSR1, AL139095.4, CAGE1, AL139095.1, AL139095.2, AL139095.3, RIOK1, HNRNPLP1, AL138878.1, AL138878.2, AL031058.1, DSP, SNRNP48, AL390026.1, BMP6, TXNDC5, BLOC1S5-TXNDC5, AL096800.1, PIP5K1P1, BLOC1S5, EEF1E1-BLOC1S5, EEF1E1, AL355499.1, AL355499.2, AL359378.1, SLC35B3.
- chr6:8,653,558–8,653,797, 1 gene, copy number 5: AL161437.1.
- chr7:49,524,208–53,366,209, 42 genes, copy number 5–11: AC092448.1, AC093775.1, VWC2, ZPBP, GNL2P1, AC034148.1, SPATA48, AC020743.1, AC020743.2, AC020743.3, IKZF1, AC124014.1, RNU6-1091P, FIGNL1, DDC, DDC-AS1, GRB10, AC005153.1, AC004920.1, AC009296.1, AC004830.2, AC004830.1, COBL, RPL7L1P2, CICP17, AC012441.2, AC012441.1, AC005999.2, ROBO2P1, AC005999.1, RN7SL292P, AC006478.1, AC006478.2, AC079763.1, AC006320.1, AC006459.1, SGO1P2, AC074397.1, POM121L12, HAUS6P1, RNF138P2, RNU1-14P.
- chr7:53,655,508–57,837,046, 163 genes, copy number 9–12 (broad region; genes not listed).
- chr18:49,036,387–49,461,347, 1 gene, copy number 6 (within-gene range 3–6): DYM.
- chr18:49,116,301–49,651,160, 18 genes, copy number 6: AC016866.2, AC044840.1, AC100778.1, AC100778.4, PRR13P4, C18orf32, RPL17-C18orf32, AC100778.2, AC100778.3, MIR1539, RPL17, SNORD58C, SNORD58A, SNORD58B, SRP72P1, LINC02837, LIPG, SMUG1P1.

Autosomal genes at a single copy (total copy number 1): 19,336. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
